Somatic mutation profile of tumor specimen TCGA-DB-5280-01A (aliquot TCGA-DB-5280-01A-01D-1468-08) from TCGA case TCGA-DB-5280, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 43.4 years (15,836 days).
Specimen TCGA-DB-5280-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c54c0674-ccaa-4c01-9d5f-f5b7930dcd23.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-5280-10A (Blood Derived Normal), aliquot TCGA-DB-5280-10A-01D-1468-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7ed60c26-34cc-407a-a590-ed5552421db0

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 51/125 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 32/66 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.464C>A p.T155N | Missense Mutation (SNP) | VAF 55/111 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as rs786202752, CM942117, HM090066, COSV52692291, COSV52711720, COSV52741190, COSV52782333; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CST8 | c.202G>C p.V68L | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as COSV55671481; called by muse, mutect2
- DSG4 | c.1483C>T p.P495S | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57393505; called by muse, mutect2, varscan2
- FCRL3 | c.1157C>A p.T386N | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV63842855; called by muse, mutect2, varscan2
- FMO1 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV61446403; called by muse, mutect2, varscan2
- LINGO2 | c.560G>A p.C187Y | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.735); catalogued as rs1456131363, COSV58061105; called by muse, mutect2, varscan2
- MYO10 | c.3725G>A p.R1242H | Missense Mutation (SNP) | VAF 26/233 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368834881; called by muse, mutect2, varscan2
- NUMBL | c.578C>G p.A193G | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV53285982; called by muse, mutect2, varscan2
- VRK1 | c.593A>G p.Y198C | Missense Mutation (SNP) | VAF 86/204 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53710085; called by muse, mutect2, varscan2
- LACC1 | c.527del p.G176Efs*3 | Frame Shift Del (DEL) | VAF 44/148 reads (30%) | called by mutect2, pindel, varscan2
- CARD16 | c.34C>T p.L12= | Silent (SNP) | VAF 30/490 reads (6%) | catalogued as rs762518562, COSV65212785, COSV65213126; called by muse, mutect2
- ITPKC | c.372A>C p.L124= | Silent (SNP) | VAF 45/133 reads (34%) | catalogued as COSV54575638; called by muse, mutect2, varscan2
- TUT4 | c.4929G>A p.S1643= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as rs747893717, COSV57116040; called by muse, mutect2, varscan2
